Somatic mutation profile of tumor specimen MMRF_2090_1_BM_CD138pos (aliquot MMRF_2090_1_BM_CD138pos_T1_KHS5U_L08150) from MMRF case MMRF_2090, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 52.6 years (19,202 days).
Specimen MMRF_2090_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 53359d3d-1f27-43ca-969f-7b3e2ed954b1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2090_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2090_1_PB_Whole_C2_KHS5U_L12834; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/28dc2323-9a3b-42ce-aaba-082eeee2a32e

The open-access MAF lists 88 somatic variants for this specimen: 33 protein-altering or splice-affecting, 8 silent, 47 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, 3'UTR 23, Intron 10, Silent 8, 5'UTR 7, Frame Shift Del 3, RNA 3, Splice Site 2, 3'Flank 2, 5'Flank 2, Frame Shift Ins 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CFTR | c.2834C>T p.S945L | Missense Mutation (SNP) | VAF 85/196 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs397508442, CM930123; ClinVar: pathogenic / drug response; called by muse, mutect2, varscan2
- ADAM29 | c.930C>G p.H310Q | Missense Mutation (SNP) | VAF 105/276 reads (38%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV100822298; called by muse, mutect2, varscan2
- AKAP6 | c.4384C>T p.H1462Y | Missense Mutation (SNP) | VAF 68/90 reads (76%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.335); catalogued as rs1224431842; called by muse, mutect2, varscan2
- BRWD1 | c.1036C>T p.H346Y | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as COSV60898919; called by muse, mutect2, varscan2
- CMYA5 | c.7927C>A p.R2643S | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.2); catalogued as rs199557617; called by muse, mutect2, varscan2
- DDX3X | c.1226C>T p.S409F (on ENST00000399959; = p.S410F on NM_001356.5) | Missense Mutation (SNP) | VAF 30/40 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV67863744; called by muse, mutect2, varscan2
- IGHV4-39 | c.17A>G p.K6R | Missense Mutation (SNP) | VAF 36/62 reads (58%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.054); catalogued as rs1402982895; called by muse, varscan2
- IGHV4-39 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 28/51 reads (55%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.211); catalogued as rs587658016; called by muse, varscan2
- NR2F1 | c.670G>A p.A224T | Missense Mutation (SNP) | VAF 80/174 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV59067851; called by muse, mutect2, varscan2
- PAGR1 | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs780516799; called by muse, mutect2, varscan2
- SPATA48 | c.919G>A p.V307I | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs1251058165; called by muse, mutect2, varscan2
- TENT5C | c.476del p.N159Tfs*9 | Frame Shift Del (DEL) | VAF 59/166 reads (36%) | catalogued as COSV65616437; called by mutect2, pindel, varscan2
- C7orf25 | c.80C>T p.S27L | Missense Mutation (SNP) | VAF 141/371 reads (38%) | SIFT tolerated (0.7); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCM2L | c.1204T>G p.C402G (on ENST00000452892 / NM_001365692.1; = p.T380= on NM_080625.4) | Missense Mutation (SNP) | VAF 75/162 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- CD38 | c.549C>A p.N183K | Missense Mutation (SNP) | VAF 60/154 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ERMAP | c.80T>A p.V27E | Missense Mutation (SNP) | VAF 156/443 reads (35%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- FAM161B | c.2056G>C p.E686Q (on ENST00000651776; = p.E623Q on NM_152445.3) | Missense Mutation (SNP) | VAF 82/109 reads (75%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- GRIA2 | c.1442G>T p.W481L | Missense Mutation (SNP) | VAF 75/203 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- GRIN1 | c.2013+2T>G p.X671_splice | Splice Site (SNP) | VAF 50/130 reads (38%) | called by muse, mutect2, varscan2
- HEG1 | c.782_783insGAC p.S261_F262insT | In Frame Ins (INS) | VAF 62/141 reads (44%) | called by mutect2, varscan2
- IGKC | c.182G>C p.S61T | Missense Mutation (SNP) | VAF 41/53 reads (77%) | SIFT tolerated (0.06); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- KLHL42 | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 49/127 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- LIN9 | c.62C>T p.S21L | Missense Mutation (SNP) | VAF 64/199 reads (32%) | PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- LRP1 | c.11432C>A p.S3811* | Nonsense Mutation (SNP) | VAF 54/128 reads (42%) | called by muse, mutect2, varscan2
- NCAPD3 | c.1351G>A p.D451N | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- OR5H1 | c.707A>C p.K236T | Missense Mutation (SNP) | VAF 54/121 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PHF3 | c.2712del p.V906Lfs*35 | Frame Shift Del (DEL) | VAF 67/102 reads (66%) | called by mutect2, pindel, varscan2
- SALL4 | c.1775G>A p.R592K | Missense Mutation (SNP) | VAF 131/303 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SEZ6L | c.3045+1G>A p.X1015_splice | Splice Site (SNP) | VAF 129/307 reads (42%) | called by muse, mutect2, varscan2
- SPEF2 | c.5076A>C p.E1692D | Missense Mutation (SNP) | VAF 104/270 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- VPS33B | c.781del p.S261Vfs*15 | Frame Shift Del (DEL) | VAF 10/108 reads (9%) | called by mutect2, pindel*
- ZC3H12A | c.1718dup p.M573Ifs*27 | Frame Shift Ins (INS) | VAF 21/62 reads (34%) | called by mutect2, pindel, varscan2
- ZNF708 | c.1259A>G p.Y420C | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- ALDH2 | c.471C>T p.H157= | Silent (SNP) | VAF 31/70 reads (44%) | catalogued as rs575953094, COSV99923414; called by muse, mutect2, varscan2
- APOB | c.5667A>T p.S1889= | Silent (SNP) | VAF 85/195 reads (44%) | called by muse, mutect2, varscan2
- DHRS4L2 | c.243G>A p.L81= | Silent (SNP) | VAF 35/43 reads (81%) | catalogued as rs1052728921, COSV58729930; called by muse, mutect2, varscan2
- EPS8 | c.1290T>C p.V430= | Silent (SNP) | VAF 55/144 reads (38%) | catalogued as rs770142121; called by muse, mutect2, varscan2
- H2AC4 | c.303G>A p.V101= | Silent (SNP) | VAF 56/135 reads (41%) | called by muse, mutect2, varscan2
- IGHD3-3 | c.31C>G p.*11= | Silent (SNP) | VAF 10/14 reads (71%) | catalogued as rs782815904; called by muse, mutect2, varscan2
- IGHD3-3 | c.30C>T p.Y10= | Silent (SNP) | VAF 10/13 reads (77%) | catalogued as rs781896755; called by muse, mutect2, varscan2
- PCLO | c.5160G>T p.L1720= | Silent (SNP) | VAF 60/143 reads (42%) | catalogued as rs1438679111; called by muse, mutect2, varscan2
- ACSS2 | chr20:34876596 G>C | 5'Flank (SNP) | VAF 19/54 reads (35%) | catalogued as rs1161266208; called by muse, mutect2, varscan2
- AFF2 | c.*3667T>C | 3'UTR (SNP) | VAF 31/33 reads (94%) | called by muse, mutect2, varscan2
- ALDH3A2 | chr17:19648626 A>G | 5'Flank (SNP) | VAF 49/141 reads (35%) | called by muse, mutect2, varscan2
- ANXA2R | c.-119T>C | 5'UTR (SNP) | VAF 22/38 reads (58%) | called by muse, mutect2, varscan2
- BNIP3P1 | n.781G>A | RNA (SNP) | VAF 105/194 reads (54%) | called by muse, mutect2, varscan2
- CFAP410 | c.*544dup | 3'UTR (INS) | VAF 40/116 reads (34%) | called by mutect2, pindel, varscan2
- CNOT6 | c.490+9T>C | Intron (SNP) | VAF 75/169 reads (44%) | called by muse, mutect2, varscan2
- CTSH | c.492+27del | Intron (DEL) | VAF 51/128 reads (40%) | called by mutect2, pindel, varscan2
- DCAF4L2 | c.*1680A>T | 3'UTR (SNP) | VAF 134/148 reads (91%) | catalogued as COSV60482683; called by muse, mutect2, varscan2
- DNAH7 | c.1353+1809del | Intron (DEL) | VAF 22/56 reads (39%) | catalogued as rs1013271476; called by mutect2, varscan2
- EBF1 | c.*2077T>C | 3'UTR (SNP) | VAF 36/63 reads (57%) | called by muse, mutect2, varscan2
- EDIL3 | c.*2248C>T | 3'UTR (SNP) | VAF 15/35 reads (43%) | called by muse, mutect2, varscan2
- EPB41L4B | c.*1991G>A | 3'UTR (SNP) | VAF 63/136 reads (46%) | catalogued as rs891443672; called by muse, mutect2, varscan2
- EPN3 | c.892-29T>G | Intron (SNP) | VAF 38/91 reads (42%) | called by muse, mutect2, varscan2
- EWSR1 | c.975-1215G>A | Intron (SNP) | VAF 27/64 reads (42%) | called by muse, mutect2, varscan2
- FDFT1 | c.-75G>A | 5'UTR (SNP) | VAF 13/18 reads (72%) | called by muse, mutect2, varscan2
- GABPB1 | c.-1+698G>A | Intron (SNP) | VAF 50/132 reads (38%) | catalogued as rs985502954; called by muse, mutect2, varscan2
- GCSAM | c.*1383T>A | 3'UTR (SNP) | VAF 29/95 reads (31%) | called by muse, mutect2, varscan2
- GCSAM | c.*1293T>C | 3'UTR (SNP) | VAF 25/87 reads (29%) | called by muse, mutect2, varscan2
- GFAP | c.*26C>T | 3'UTR (SNP) | VAF 3/50 reads (6%) | catalogued as rs1203339009; called by muse, mutect2
- HDGFL3 | c.-11G>A | 5'UTR (SNP) | VAF 30/54 reads (56%) | called by muse, mutect2, varscan2
- IGHV4-39 | c.-29A>G | 5'UTR (SNP) | VAF 18/28 reads (64%) | catalogued as rs369647413; called by muse, varscan2
- IGKV2-26 | n.267G>C | RNA (SNP) | VAF 33/47 reads (70%) | called by muse, mutect2, varscan2
- KRT79 | c.*65C>A | 3'UTR (SNP) | VAF 32/74 reads (43%) | catalogued as COSV100398545; called by muse, mutect2, varscan2
- LALBA | c.*12C>T | 3'UTR (SNP) | VAF 37/104 reads (36%) | called by muse, mutect2, varscan2
- LCORL | c.*2600G>A | 3'UTR (SNP) | VAF 160/351 reads (46%) | called by muse, mutect2, varscan2
- LEF1 | c.*216G>A | 3'UTR (SNP) | VAF 52/136 reads (38%) | called by muse, mutect2, varscan2
- NCBP2 | c.400-158A>C | Intron (SNP) | VAF 25/59 reads (42%) | called by muse, mutect2
- NEURL1 | c.*374G>C | 3'UTR (SNP) | VAF 61/144 reads (42%) | called by muse, mutect2, varscan2
- PHF21A | chr11:45933222 C>T | 3'Flank (SNP) | VAF 56/165 reads (34%) | catalogued as rs967875315; called by muse, mutect2, varscan2
- PYGB | c.-74G>A | 5'UTR (SNP) | VAF 51/121 reads (42%) | called by muse, mutect2, varscan2
- RCOR1 | c.*3331G>A | 3'UTR (SNP) | VAF 19/30 reads (63%) | called by muse, mutect2, varscan2
- REEP1 | c.*1603T>C | 3'UTR (SNP) | VAF 18/56 reads (32%) | called by muse, mutect2, varscan2
- RUNX1T1 | c.*3445T>A | 3'UTR (SNP) | VAF 68/79 reads (86%) | catalogued as rs1013899950; called by muse, mutect2, varscan2
- SIM1 | c.*395G>A | 3'UTR (SNP) | VAF 24/61 reads (39%) | called by muse, mutect2, varscan2
- SLC4A1 | c.*1657G>A | 3'UTR (SNP) | VAF 49/108 reads (45%) | called by muse, mutect2, varscan2
- SPATA31C2 | n.2298A>C | RNA (SNP) | VAF 9/31 reads (29%) | called by muse, mutect2, varscan2
- TACC1 | c.-198G>A | 5'UTR (SNP) | VAF 20/28 reads (71%) | called by muse, mutect2, varscan2
- TAFA1 | c.*30C>T | 3'UTR (SNP) | VAF 143/571 reads (25%) | catalogued as COSV101524494; called by muse, mutect2, varscan2
- TBC1D31 | c.1033-1392C>T | Intron (SNP) | VAF 42/55 reads (76%) | called by muse, mutect2, varscan2
- TCF4 | c.1070-33T>A | Intron (SNP) | VAF 54/121 reads (45%) | called by muse, mutect2, varscan2
- TRAK2 | c.*1236T>A | 3'UTR (SNP) | VAF 65/142 reads (46%) | catalogued as rs1035686935; called by muse, mutect2, varscan2
- TRPC4AP | c.*362C>T | 3'UTR (SNP) | VAF 53/117 reads (45%) | called by muse, mutect2, varscan2
- VDR | chr12:47842331 G>A | 3'Flank (SNP) | VAF 60/129 reads (47%) | catalogued as rs1331916538; called by muse, mutect2, varscan2
- ZNF280D | c.*184T>G | 3'UTR (SNP) | VAF 96/229 reads (42%) | called by muse, mutect2, varscan2
- ZNF333 | c.511+1800C>T | Intron (SNP) | VAF 13/22 reads (59%) | called by muse, mutect2, varscan2
- ZNF805 | c.-183G>T | 5'UTR (SNP) | VAF 38/86 reads (44%) | catalogued as rs1006335688; called by muse, mutect2, varscan2
